CPTAC case C3L-07154 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/52432728-0239-496a-8077-eb386cb7f28d

Demographics
Sex at birth: male; Race: white; Year of birth: 1967; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 53.8 years (19,644 days); Year of diagnosis: 2020; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 221 days; Progression or recurrence: yes; Days to last follow up: 221 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 10.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Oxaliplatin; Days to treatment start: 40 days; Days to treatment end: 88 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Oxaliplatin; Days to treatment start: 124 days; Days to treatment end: 189 days; Treatment outcome: Partial Response.

Follow-up (1 entry)
- Days to follow up: 221 days; Karnofsky performance status: 50; ECOG performance status: 3.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-07154-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 22 days; Initial weight: 550 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07154-22: Section location: Stomach, NOS; Percent tumor nuclei: 70; Percent necrosis: 5.
- Sample C3L-07154-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 22 days; Method of sample procurement: Blood Draw.
